Somatic mutation profile of tumor specimen ALCH-B3DL-TTP1-A (aliquot ALCH-B3DL-TTP1-A-2-0-D-A799-36) from ALCHEMIST case ALCH-B3DL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.0 years (24,481 days).
Specimen ALCH-B3DL-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5bca7346-caa9-4829-aed0-9597b0aa1362.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3DL-NB1-A (Blood Derived Normal), aliquot ALCH-B3DL-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4868789e-e036-4eb3-b5f5-cb13c7988a6c

The open-access MAF lists 33 somatic variants for this specimen: 23 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 7, Nonsense Mutation 2, Frame Shift Del 1, RNA 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 62/599 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2
- ADAMTS6 | c.1016del p.G339Efs*73 | Frame Shift Del (DEL) | VAF 22/226 reads (10%) | catalogued as COSV66857851; called by mutect2, varscan2
- ADGRG4 | c.9020G>A p.R3007Q | Missense Mutation (SNP) | VAF 20/310 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.062); catalogued as rs750733398, COSV54953580; called by muse, mutect2
- ARHGAP23 | c.1573C>T p.R525* | Nonsense Mutation (SNP) | VAF 3/38 reads (8%) | catalogued as rs1396014049; called by muse, mutect2
- FAM83D | c.1301C>T p.T434M | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs750502040, COSV54157194; called by muse, mutect2, varscan2
- GPLD1 | c.1390G>A p.V464M | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.678); catalogued as rs144999503; called by muse, mutect2, varscan2
- NIPAL4 | c.530G>C p.G177A | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV100357367; called by muse, mutect2
- PCDHGA7 | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.746); catalogued as rs768364409; called by muse, mutect2
- PDHA2 | c.1088G>A p.G363D | Missense Mutation (SNP) | VAF 45/511 reads (9%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.723); catalogued as COSV54777507; called by muse, mutect2
- SETD5 | c.2908G>T p.V970L | Missense Mutation (SNP) | VAF 39/506 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56712776; called by muse, mutect2
- SI | c.2347C>A p.P783T | Missense Mutation (SNP) | VAF 40/469 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52293821; called by muse, mutect2
- VWA5B1 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 24/254 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0.36); catalogued as rs1428056571; called by muse, mutect2
- BCO1 | c.1496A>G p.E499G | Missense Mutation (SNP) | VAF 15/418 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EPS8 | c.349A>G p.I117V | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2
- FTH1 | c.41A>T p.H14L | Missense Mutation (SNP) | VAF 48/690 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2
- GPRASP1 | c.1172C>T p.A391V | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- LOXHD1 | c.2653G>T p.E885* | Nonsense Mutation (SNP) | VAF 7/82 reads (9%) | called by muse, mutect2
- MRC1 | c.3421T>A p.F1141I | Missense Mutation (SNP) | VAF 50/662 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2
- PCDHA4 | c.1403A>G p.N468S | Missense Mutation (SNP) | VAF 64/840 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PER2 | c.1936G>A p.G646R | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.11); called by muse, mutect2
- PPP4R1 | c.2414T>A p.V805D (on ENST00000400556 / NM_001042388.3; = p.V788D on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/229 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- SI | c.2348C>A p.P783Q | Missense Mutation (SNP) | VAF 40/466 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- UBE2Q1 | c.346C>G p.P116A | Missense Mutation (SNP) | VAF 24/221 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AKR7A2 | c.639C>T p.P213= | Silent (SNP) | VAF 41/560 reads (7%) | catalogued as rs1178069662; called by muse, mutect2
- ATF7 | c.1113A>G p.L371= (on ENST00000548446 / NM_001366555.2; = p.L360= on NM_006856.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 31/515 reads (6%) | called by muse, mutect2
- CDK12 | c.537C>T p.L179= | Silent (SNP) | VAF 27/296 reads (9%) | catalogued as rs151330887; called by muse, mutect2
- GTF2F1 | c.267G>A p.K89= | Silent (SNP) | VAF 21/172 reads (12%) | called by muse, mutect2, varscan2
- KLF3 | c.441G>T p.P147= | Silent (SNP) | VAF 70/784 reads (9%) | called by muse, mutect2
- OR2M5 | c.219C>G p.L73= | Silent (SNP) | VAF 22/262 reads (8%) | catalogued as COSV63546909; called by muse, mutect2
- SEZ6L | c.2682A>G p.G894= | Silent (SNP) | VAF 9/176 reads (5%) | called by muse, mutect2
- AL353804.4 | chrX:73824272 C>T | 5'Flank (SNP) | VAF 37/392 reads (9%) | catalogued as rs759258501; called by muse, mutect2
- OSBPL2 | c.996+120A>G | Intron (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2, varscan2
- TPTE2P1 | n.777C>T | RNA (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
